Somatic mutation profile of tumor specimen TCGA-UT-A88E-01B (aliquot TCGA-UT-A88E-01B-11D-A39R-32) from TCGA case TCGA-UT-A88E, project TCGA-MESO (Mesothelioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Epithelioid mesothelioma, malignant; Tissue or organ of origin: Pleura, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 74.9 years (27,347 days).
Specimen TCGA-UT-A88E-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4e992800-4c9f-4584-8815-d7a43253b16e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-UT-A88E-10A (Blood Derived Normal), aliquot TCGA-UT-A88E-10A-01D-A39U-32; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/74e4339f-32dc-47f5-ac4c-d4d1aa66d18e

The open-access MAF lists 49 somatic variants for this specimen: 36 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 12, Nonsense Mutation 2, In Frame Del 2, 5'Flank 1, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRE2 | c.1082C>A p.T361K | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.073); catalogued as COSV59693385; called by muse, mutect2, varscan2
- CACNA1B | c.4259A>G p.Q1420R | Missense Mutation (SNP) | VAF 43/64 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53140946; called by muse, mutect2, varscan2
- CRYGA | c.424C>T p.R142W | Missense Mutation (SNP) | VAF 41/108 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); catalogued as rs1474537753, COSV58015164; called by muse, mutect2, varscan2
- DBX1 | c.23C>T p.A8V | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as rs1428796043, COSV104389898; called by muse, mutect2, varscan2
- DERL1 | c.50A>G p.Y17C | Missense Mutation (SNP) | VAF 65/165 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.164); catalogued as rs777366277; called by muse, mutect2, varscan2
- DLL1 | c.1357G>A p.A453T | Missense Mutation (SNP) | VAF 16/23 reads (70%) | SIFT tolerated (0.11); PolyPhen benign (0.244); catalogued as rs763449437, COSV64536814; called by muse, mutect2, varscan2
- EML5 | c.2032C>T p.R678* | Nonsense Mutation (SNP) | VAF 10/37 reads (27%) | catalogued as rs762453622, COSV61341366; called by muse, mutect2, varscan2
- ENOX2 | c.604G>A p.V202I (on ENST00000338144 / NM_001382520.1; = p.V173I on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs754363472; called by muse, mutect2, varscan2
- EXOC3L4 | c.1386-2A>G p.X462_splice | Splice Site (SNP) | VAF 9/148 reads (6%) | catalogued as rs1481097151, COSV101197626; called by muse, mutect2
- FUT4 | c.236C>T p.S79F | Missense Mutation (SNP) | VAF 55/79 reads (70%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.445); catalogued as rs1022264636, COSV62469371; called by muse, mutect2, varscan2
- HIC1 | c.2105G>A p.G702D (on ENST00000322941 / NM_001098202.1; = p.G683D on NM_006497.4) | Missense Mutation (SNP) | VAF 44/95 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.984); catalogued as rs1224227061; called by muse, mutect2, varscan2
- IL1RAP | c.1253A>G p.E418G | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs774347153; called by muse, mutect2, varscan2
- KMT2A | c.281C>T p.S94L | Missense Mutation (SNP) | VAF 16/290 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); catalogued as rs782775993, COSV63292754; called by muse, mutect2
- LCE5A | c.113C>A p.P38H | Missense Mutation (SNP) | VAF 69/193 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.057); catalogued as COSV57500190; called by muse, mutect2, varscan2
- MEP1B | c.1330C>A p.P444T | Missense Mutation (SNP) | VAF 77/188 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.014); catalogued as COSV52499777; called by muse, mutect2, varscan2
- NPTXR | c.442C>A p.Q148K | Missense Mutation (SNP) | VAF 46/64 reads (72%) | SIFT tolerated (0.65); PolyPhen benign (0.017); catalogued as COSV60728474; called by muse, mutect2, varscan2
- PHKA1 | c.2921G>A p.R974H | Missense Mutation (SNP) | VAF 20/30 reads (67%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs1322897539, COSV59801415; called by muse, mutect2, varscan2
- RASSF9 | c.979A>C p.K327Q | Missense Mutation (SNP) | VAF 46/102 reads (45%) | SIFT tolerated (0.28); PolyPhen benign (0.028); catalogued as rs1211834604; called by muse, mutect2, varscan2
- ROBO2 | c.394C>G p.R132G | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1308248520, COSV100166545; called by muse, mutect2, varscan2
- ZNF18 | c.1376C>T p.T459M | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762161028, COSV104401208; called by muse, mutect2, varscan2
- CNTNAP2 | c.404C>A p.A135E | Missense Mutation (SNP) | VAF 6/87 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.534); called by muse, mutect2
- ESYT2 | c.1817A>G p.D606G (on ENST00000613624; = p.D530G on NM_020728.3) | Missense Mutation (SNP) | VAF 49/101 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- GABRA6 | c.782C>T p.S261F | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- HERC1 | c.360_362del p.K120_Y121delinsN | In Frame Del (DEL) | VAF 31/113 reads (27%) | called by mutect2, pindel, varscan2
- IL13RA1 | c.14C>T p.A5V | Missense Mutation (SNP) | VAF 14/14 reads (100%) | SIFT tolerated (0.23); PolyPhen benign (0.001); called by muse, mutect2
- KIT | c.27T>G p.D9E | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT tolerated (1); PolyPhen possibly damaging (0.588); called by muse, mutect2, varscan2
- POLR1A | c.2606T>G p.V869G | Missense Mutation (SNP) | VAF 32/41 reads (78%) | SIFT deleterious (0.01); PolyPhen benign (0.438); called by muse, mutect2, varscan2
- RP1 | c.6328C>T p.Q2110* | Nonsense Mutation (SNP) | VAF 6/47 reads (13%) | called by muse, mutect2, varscan2
- SEMA4B | c.2452_2467del p.S818Gfs*18 | Frame Shift Del (DEL) | VAF 31/133 reads (23%) | called by mutect2, pindel, varscan2
- SEMG2 | c.514A>C p.S172R | Missense Mutation (SNP) | VAF 66/195 reads (34%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.588); called by muse, mutect2, varscan2
- SETD2 | c.2969T>G p.V990G | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); called by mutect2, varscan2
- TERF2 | c.361A>G p.I121V | Missense Mutation (SNP) | VAF 42/133 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.143); called by mutect2, varscan2
- TMC3 | c.1045_1047del p.Q349del | In Frame Del (DEL) | VAF 21/71 reads (30%) | called by mutect2, pindel, varscan2
- TTN | c.95921T>G p.I31974S (on ENST00000591111; = p.I24550S on NM_003319.4) | Missense Mutation (SNP) | VAF 23/64 reads (36%) | PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF629 | c.2291G>A p.G764E | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.631); called by muse, mutect2, varscan2
- ZRANB1 | c.887C>G p.T296S | Missense Mutation (SNP) | VAF 48/102 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- AEBP1 | c.2403C>T p.S801= | Silent (SNP) | VAF 9/53 reads (17%) | catalogued as rs771073892; called by muse, mutect2, varscan2
- AQR | c.633A>T p.A211= | Silent (SNP) | VAF 27/91 reads (30%) | called by muse, mutect2, varscan2
- CCDC148 | c.465C>T p.N155= | Silent (SNP) | VAF 20/40 reads (50%) | called by muse, varscan2
- CHRNA4 | c.390C>T p.D130= | Silent (SNP) | VAF 13/116 reads (11%) | catalogued as rs375014053; called by muse, mutect2, varscan2
- FBXL12 | c.66G>C p.R22= | Silent (SNP) | VAF 45/98 reads (46%) | called by muse, mutect2, varscan2
- ITGB7 | c.1167G>A p.L389= | Silent (SNP) | VAF 35/77 reads (45%) | catalogued as rs767087706; called by muse, mutect2, varscan2
- KCNV1 | c.33G>A p.S11= | Silent (SNP) | VAF 27/69 reads (39%) | called by muse, mutect2, varscan2
- MACF1 | c.2238T>G p.L746= | Silent (SNP) | VAF 45/113 reads (40%) | called by muse, mutect2, varscan2
- MAML2 | c.91A>C p.R31= | Silent (SNP) | VAF 165/236 reads (70%) | called by muse, mutect2, varscan2
- RPL37 | c.99C>T p.T33= | Silent (SNP) | VAF 22/54 reads (41%) | called by muse, mutect2, varscan2
- TBC1D32 | c.1869A>T p.T623= | Silent (SNP) | VAF 19/40 reads (48%) | called by muse, mutect2, varscan2
- UHRF1BP1L | c.3786G>T p.G1262= | Silent (SNP) | VAF 41/111 reads (37%) | called by muse, mutect2, varscan2
- DALRD3 | chr3:49020659 G>A | 5'Flank (SNP) | VAF 17/25 reads (68%) | called by muse, mutect2, varscan2
